Gene-level copy-number profile of tumor specimen TCGA-TP-A8TT-01A from TCGA case TCGA-TP-A8TT, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.3 years (23,476 days).
Specimen TCGA-TP-A8TT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.85200111-e4f4-43fe-bd83-acf2cb93e2ca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TP-A8TT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/29a3900c-5ae3-45c1-bc01-79e7b264d540

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 5,894; copy number 2: 52,768; copy number 3: 996; copy number 4: 91; copy number 6: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TP-A8TT-01A-12D-A41J-01): tumor purity 0.58, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,638,285–22,455,740, 19 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr10:87,994,618–88,584,530, 4 genes (within-gene range 0–1): AC063965.1, MED6P1, AL353149.1, RNLS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 46 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:51,177,425–51,260,163, 1 gene, copy number 6 (within-gene range 4–6): MBTD1.
- chr17:51,249,579–56,511,659, 45 genes, copy number 6 (within-gene range 4–6): AC006141.1, UTP18, LINC02071, AC005823.2, AC005823.1, LINC02073, RPL7P48, CA10, AC002090.1, LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1, ARL2BPP8, RN7SKP14, TOM1L1, COX11, AC007485.2, AC007485.1, STXBP4, HLF, AC007638.2, AC007638.1, MMD, SMIM36, AC105021.1, GARS1P1, RNU6-1249P, TMEM100, PCTP, AC090618.1, ANKFN1, AC006600.1, AC006600.2.

Autosomal genes at a single copy (total copy number 1): 3,521. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
